Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A39J, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A39J-01A (Primary Tumor).

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

TUMOR SITE:

Right and left lobes

HISTOLOGIC TYPE:

Papillary carcinoma

TUMOR SIZE:

Greatest dimension: 3.0 (in right lobe)

FOCALITY:

Multifocal

LYMPH NODES:

None submitted

EXTENT OF INVASION (SUMMARY STAGING): PRIMARY TUMOR (pT):

pT2: Tumor >2cm but <4 cm, limited to thyroid

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

MARGINS:

Margins are uninvolved

VENOUS/LYMPHATIC INVASION:

None identified

ADDITIONAL PATHOLOGIC FINDINGS:

Parathyroid tissue present in association with the right lower thyroid lobe

Source: NCI Genomic Data Commons file 638d3512-fedf-4a4e-8acb-8ec6a84df30c (TCGA-ET-A39J.3B981FAD-AA10-4FCE-84FD-97C14CEF2EB7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).